CCDI case PBBRVP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/5e6c9e87-95d3-4484-bb49-def3a9ba18d2

Demographics
Sex at birth: male; Vital status: Alive.

Diagnoses (1)
1. Choroid plexus papilloma, NOS: ICD-O-3 morphology code: 9390/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.2 years (2,249 days).

Biospecimens (2 samples)
- Sample 0DFO11: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFO19: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
